Somatic mutation profile of tumor specimen HCM-BROD-0762-C49-01A (aliquot HCM-BROD-0762-C49-01A-01D-A87L-36) from HCMI case HCM-BROD-0762-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Abdominal fibromatosis; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.9 years (5,799 days).
Specimen HCM-BROD-0762-C49-01A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f35ee96-5102-4b85-ab9c-09a19b19b236.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0762-C49-11A (Solid Tissue Normal), aliquot HCM-BROD-0762-C49-11A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/231a856d-c9de-41a4-9748-6a207d7b2fb8

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.33_39delinsGA p.Y11* | Nonsense Mutation (DEL) | VAF 46/447 reads (10%) | called by pindel, varscan2*
- CLN8 | c.719T>A p.L240Q | Missense Mutation (SNP) | VAF 32/784 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- PPP4R3C | c.2300C>T p.T767I | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- RYR2 | c.13407A>T p.R4469S | Missense Mutation (SNP) | VAF 20/570 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2
- FZD9 | c.1308C>A p.T436= | Silent (SNP) | VAF 60/521 reads (12%) | called by muse, mutect2, varscan2
